Somatic mutation profile of tumor specimen C3L-04014-02 (aliquot CPT0233600006) from CPTAC case C3L-04014, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 57.6 years (21,035 days).
Specimen C3L-04014-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e3e92c7-8d44-40c6-8234-81647543cad6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04014-31 (Blood Derived Normal), aliquot CPT0233750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97ac218c-9e78-49f9-838d-3d65df15f01d

The open-access MAF lists 370 somatic variants for this specimen: 252 protein-altering or splice-affecting, 74 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 74, Intron 19, Nonsense Mutation 12, RNA 10, 3'UTR 6, Frame Shift Del 6, Splice Region 5, 5'UTR 4, 3'Flank 3, In Frame Del 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.72G>C p.W24C | Missense Mutation (SNP) | VAF 146/243 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960212, COSV67961561; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 300/588 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.158G>C p.R53P | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52454197; called by muse, mutect2, varscan2
- ADRA2B | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 151/598 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69787756; called by muse, mutect2, varscan2
- ARID1A | c.5270C>A p.A1757D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs775549195; called by muse, mutect2
- ARL13A | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773610188, COSV65880170; called by muse, mutect2, varscan2
- ASPM | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1462284532; called by muse, mutect2
- C11orf87 | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 69/556 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.051); catalogued as rs559668737; called by muse, mutect2, varscan2
- CATSPERE | c.2146A>G p.K716E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV63681249; called by muse, mutect2, varscan2
- CCDC74A | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 38/756 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV54608642, COSV99723938; called by muse, mutect2
- CDK11B | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100477237; called by muse, mutect2, varscan2
- CEP126 | c.3347A>G p.K1116R | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs1565372968; called by muse, mutect2, varscan2
- CNTNAP5 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 97/375 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV101444235, COSV70494453; called by muse, mutect2, varscan2
- COL25A1 | c.1014del p.I339* | Frame Shift Del (DEL) | VAF 22/207 reads (11%) | catalogued as COSV101211131, COSV67649618; called by mutect2, pindel, varscan2
- CRACDL | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as rs1205987727; called by muse, mutect2, varscan2
- CYP26B1 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV99134485; called by muse, mutect2, varscan2
- DBH | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 136/576 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.044); catalogued as rs756562846; called by muse, mutect2, varscan2
- DCAF12L1 | c.197C>G p.A66G | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.411); catalogued as rs758875700; called by muse, mutect2, varscan2
- DCAF12L1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV64422859; called by muse, mutect2, varscan2
- DCPS | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 81/848 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as rs375647806; called by muse, mutect2
- DDHD2 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs754698552; called by muse, mutect2, varscan2
- DMXL2 | c.9097C>G p.L3033V | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV51848809; called by muse, mutect2, varscan2
- DNAH6 | c.7951C>T p.R2651C | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs371507847; called by muse, mutect2, varscan2
- EPHA6 | c.1763G>T p.R588M | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1450997036, COSV101064902, COSV67563173; called by mutect2, varscan2
- FADD | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs1474471074; called by muse, mutect2
- FBXW8 | c.121G>C p.V41L (on ENST00000652555 / NM_153348.3; = p.X40_splice on NM_012174.1) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59298788; called by muse, mutect2, varscan2
- FSIP2 | c.17657C>T p.S5886F | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs769305196; called by muse, mutect2, varscan2
- FTCD | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 113/506 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99385000; called by muse, mutect2, varscan2
- FYN | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs766184115; called by muse, mutect2, varscan2
- H2AC14 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs762907097; called by muse, mutect2, varscan2
- H2BC17 | c.268_271dup p.T91Nfs*? | Frame Shift Ins (INS) | VAF 143/888 reads (16%) | catalogued as rs1395999759; called by mutect2, pindel, varscan2
- HES6 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 89/513 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1165328038; called by muse, mutect2, varscan2
- IL12RB1 | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 69/610 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100442897; called by mutect2, varscan2
- INO80B | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as rs1365773574, COSV51969567; called by muse, mutect2, varscan2
- KMT2B | c.3981G>T p.R1327S | Missense Mutation (SNP) | VAF 68/406 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99720875; called by muse, mutect2, varscan2
- LBR | c.1588A>G p.T530A | Missense Mutation (SNP) | VAF 103/302 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs771949470; called by muse, mutect2, varscan2
- LRP1B | c.12664G>A p.E4222K | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.985); catalogued as COSV67218008; called by muse, mutect2
- LRP1B | c.4064A>T p.N1355I | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101253519; called by muse, mutect2, varscan2
- LRRCC1 | c.1186A>T p.N396Y | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV64483906; called by muse, mutect2, varscan2
- LRRIQ4 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.068); catalogued as COSV100540325; called by muse, mutect2
- MAPK8IP3 | c.1408G>T p.V470F | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV51726313; called by muse, mutect2, varscan2
- MAPT | c.2393G>A p.R798Q (on ENST00000262410 / NM_001377265.1; = p.R406Q on NM_005910.5) | Missense Mutation (SNP) | VAF 143/684 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs758074229; called by muse, mutect2, varscan2
- MRM2 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 301/543 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54248808; called by muse, mutect2, varscan2
- MSC | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 105/399 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100335602; called by muse, mutect2, varscan2
- MTHFSD | c.1096C>A p.R366S (on ENST00000360900 / NM_001159377.2; = p.R365S on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV59802538, COSV59804298; called by muse, mutect2, varscan2
- MTUS1 | c.2683G>C p.D895H (on ENST00000262102 / NM_001363061.1; = p.D61H on NM_020749.4) | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773931133, COSV99870863; called by muse, mutect2
- MUC16 | c.10817C>T p.S3606F | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); catalogued as COSV67442962; called by muse, mutect2, varscan2
- NEURL1 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63914634; called by muse, mutect2, varscan2
- NSFL1C | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as rs763644707; called by muse, mutect2
- NTM | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100869851; called by muse, mutect2
- NUP107 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1478756336; called by muse, mutect2
- OR10V1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs559488515, COSV100276309, COSV55698691; called by muse, mutect2
- OR4C46 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 28/535 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); catalogued as COSV60220294; called by muse, mutect2
- OR4D5 | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100190012, COSV58309649; called by muse, mutect2, varscan2
- OR5AR1 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs924005598; called by muse, mutect2, varscan2
- PAPPA2 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 186/650 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62779980; called by muse, mutect2, varscan2
- PCDHGA11 | c.1839C>G p.S613R | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV53924675; called by muse, mutect2, varscan2
- PPP1R12A | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1463443429; called by muse, mutect2, varscan2
- PRAMEF4 | c.1022T>G p.V341G | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV52439591; called by mutect2, varscan2
- PRKD1 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 148/448 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs761182562; called by muse, mutect2, varscan2
- PTDSS2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as rs541518220; called by muse, mutect2
- PTK7 | c.2239G>T p.E747* | Nonsense Mutation (SNP) | VAF 80/288 reads (28%) | catalogued as COSV100030800; called by muse, mutect2, varscan2
- RARS1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.098); catalogued as rs148161788, COSV51562156, COSV51565564; called by muse, mutect2, varscan2
- REG3G | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 56/252 reads (22%) | catalogued as COSV99709705; called by muse, mutect2, varscan2
- RPUSD1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 137/330 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as rs752397101, COSV50100235, COSV50103164; called by muse, varscan2
- RYR1 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 119/378 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100614214; called by muse, mutect2, varscan2
- RYR1 | c.15002A>G p.E5001G | Missense Mutation (SNP) | VAF 45/512 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs1443667188; called by muse, mutect2
- SAMD7 | c.329del p.R110Kfs*10 | Frame Shift Del (DEL) | VAF 21/195 reads (11%) | catalogued as COSV59420645; called by mutect2, pindel
- SCN3A | c.2416G>C p.E806Q | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51802729; called by muse, mutect2
- SGIP1 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs781666530; called by muse, mutect2, varscan2
- SLC23A3 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs763989453; called by muse, mutect2, varscan2
- SLC25A32 | c.932G>C p.R311T | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV52569591; called by muse, mutect2
- SPATS2L | c.1138A>G p.T380A | Missense Mutation (SNP) | VAF 63/393 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62347252; called by muse, mutect2, varscan2
- SSTR1 | c.1154C>A p.T385K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); catalogued as rs761324298, COSV57455803; called by muse, varscan2
- STRA6 | c.1841-2A>T p.X614_splice | Splice Site (SNP) | VAF 36/168 reads (21%) | catalogued as COSV99997610; called by muse, mutect2, varscan2
- TACR3 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as rs950254837, COSV100510053; called by muse, mutect2, varscan2
- TGM6 | c.1723G>C p.D575H | Missense Mutation (SNP) | VAF 128/619 reads (21%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.602); catalogued as COSV52477712; called by muse, mutect2, varscan2
- TM2D1 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1323787197; called by muse, mutect2, varscan2
- TMEM11 | c.18G>C p.R6S | Missense Mutation (SNP) | VAF 350/706 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs780980148; called by muse, mutect2, varscan2
- TMEM260 | c.1444C>G p.P482A | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99840753; called by muse, mutect2, varscan2
- TRPC6 | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723687; called by muse, mutect2, varscan2
- TTN | c.79546C>A p.P26516T (on ENST00000591111; = p.P19092T on NM_003319.4) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | PolyPhen possibly damaging (0.801); catalogued as COSV60015382; called by muse, mutect2, varscan2
- TTN | c.42206G>T p.R14069L (on ENST00000591111; = p.R6645L on NM_003319.4) | Missense Mutation (SNP) | VAF 139/439 reads (32%) | PolyPhen benign (0.14); catalogued as rs185689179, COSV60245457; called by muse, mutect2, varscan2
- TTN | c.22778G>A p.C7593Y (on ENST00000591111; = p.C6666Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/130 reads (12%) | PolyPhen probably damaging (0.961); catalogued as rs763596594, COSV100594392; called by muse, mutect2, varscan2
- WNT2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 54/532 reads (10%) | catalogued as COSV55414126; called by muse, mutect2, varscan2
- XIRP2 | c.4780C>A p.L1594M (on ENST00000628543; = p.L1769M on NM_152381.6) | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.564); catalogued as rs761118120; called by muse, mutect2, varscan2
- XIRP2 | c.6257C>A p.T2086K (on ENST00000628543; = p.T2261K on NM_152381.6) | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54711435; called by muse, mutect2, varscan2
- ZEB1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58035498, COSV58039665; called by muse, mutect2, varscan2
- ZNF627 | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1223123505; called by muse, mutect2, varscan2
- ABAT | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 123/489 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ADAMTS12 | c.4751G>A p.R1584K | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS14 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AHNAK2 | c.10166G>A p.G3389E | Missense Mutation (SNP) | VAF 121/671 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ALDH5A1 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 224/718 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- AMER1 | c.1969A>T p.R657W | Missense Mutation (SNP) | VAF 119/235 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANGEL1 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2
- ANKIB1 | c.1758G>C p.E586D | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ANKRD30A | c.740C>A p.T247N (on ENST00000611781; = p.T191N on NM_052997.2) | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ANKRD30A | c.2989T>A p.C997S (on ENST00000611781; = p.C941S on NM_052997.2) | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARGLU1 | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 40/569 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); called by muse, mutect2
- ARNT | c.2212T>G p.S738A | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2
- ATP13A5 | c.2908T>A p.S970T | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- BCAN | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BMP1 | c.364G>C p.A122P | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by mutect2, varscan2
- C17orf78 | c.762T>A p.D254E | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2
- C1orf94 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2
- CAMSAP3 | c.2976C>G p.D992E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CASZ1 | c.2767C>G p.H923D | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCDC173 | c.1533C>A p.D511E | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC50 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2
- CCDC74B | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CD1A | c.222C>G p.N74K | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.274); called by muse, mutect2
- CD37 | c.607A>T p.R203W | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- CDCA2 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.568); called by muse, mutect2
- CEBPZ | c.1253_1255del p.G418del | In Frame Del (DEL) | VAF 36/273 reads (13%) | called by mutect2, pindel, varscan2
- CFAP54 | c.6620C>T p.A2207V | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CFH | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CFHR4 | c.748T>A p.Y250N (on ENST00000367416 / NM_001201551.2; = p.Y251N on NM_001201550.3) | Missense Mutation (SNP) | VAF 128/304 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.579); called by muse, varscan2
- CHRD | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 64/410 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CNKSR2 | c.2421G>C p.Q807H | Missense Mutation (SNP) | VAF 104/201 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CPQ | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CSMD3 | c.5045G>T p.G1682V (on ENST00000297405 / NM_001363185.1; = p.G1578V on NM_052900.3) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CTAGE1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- CTSE | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DDX43 | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- DLC1 | c.1234A>G p.N412D | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJB13 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP6 | c.33G>C p.K11N | Missense Mutation (SNP) | VAF 21/429 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DPYS | c.1443G>T p.R481= | Splice Region (SNP) | VAF 68/493 reads (14%) | called by muse, mutect2, varscan2
- DST | c.6617A>G p.E2206G | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYNC2H1 | c.6652G>A p.E2218K | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2
- EFCAB10 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- EMSY | c.3833G>A p.S1278N | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ENPEP | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA5 | c.2894G>T p.G965V | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHA5 | c.2367G>C p.K789N | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- FAM227B | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM98B | c.190A>T p.N64Y | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- FCHSD2 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FGFR1OP2 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- FILIP1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLT1 | c.2886del p.S962Rfs*16 | Frame Shift Del (DEL) | VAF 40/328 reads (12%) | called by mutect2, pindel, varscan2
- FREM2 | c.1877G>T p.R626I | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FRMPD2 | c.3739A>G p.S1247G | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by mutect2, varscan2
- GAD1 | c.638+1G>T p.X213_splice | Splice Site (SNP) | VAF 61/393 reads (16%) | called by muse, mutect2, varscan2
- GLCCI1 | c.1351G>T p.V451F | Missense Mutation (SNP) | VAF 158/280 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GOLGA6L2 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 103/642 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by mutect2, varscan2
- GOLPH3 | c.8C>G p.S3W | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- GPR15 | c.173T>A p.L58* | Nonsense Mutation (SNP) | VAF 115/302 reads (38%) | called by muse, mutect2, varscan2
- GPR158 | c.2119C>A p.H707N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GPR173 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPR50 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- GRIN3A | c.2426G>A p.S809N | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GTF3C4 | c.2119A>T p.I707F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- GTF3C5 | c.1454G>C p.G485A | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HHLA1 | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD11B1L | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.144); called by muse, mutect2
- HTR5A | c.498G>T p.W166C | Missense Mutation (SNP) | VAF 187/544 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IAPP | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ICE1 | c.1424A>G p.K475R | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGLC2 | c.138C>A p.S46R | Missense Mutation (SNP) | VAF 203/934 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- IL2 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ISM2 | c.1397A>T p.D466V | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- JPT2 | c.521A>T p.H174L | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNK12 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCTD16 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM6B | c.4918A>G p.S1640G (on ENST00000448097 / NM_001348716.1; = p.S1679G on NM_001080424.2) | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KIAA1755 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2, varscan2
- KMT2D | c.5320G>T p.E1774* | Nonsense Mutation (SNP) | VAF 72/133 reads (54%) | called by muse, mutect2, varscan2
- KRT6C | c.1686C>G p.Y562* | Nonsense Mutation (SNP) | VAF 112/440 reads (25%) | called by muse, mutect2, varscan2
- LAIR2 | c.425del p.P142Qfs*13 | Frame Shift Del (DEL) | VAF 86/184 reads (47%) | called by mutect2, varscan2
- LAMC2 | c.1377C>G p.C459W | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LNX2 | c.1241T>G p.V414G | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRFN5 | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRIT1 | c.615T>A p.C205* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- LRRC30 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- MAP6 | c.1409T>A p.L470H | Missense Mutation (SNP) | VAF 41/363 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- MEDAG | c.910T>A p.*304Rext*3 | Nonstop Mutation (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- MUC16 | c.38566C>G p.P12856A | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- MYH14 | c.2794G>T p.A932S | Missense Mutation (SNP) | VAF 35/455 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2
- MYO16 | c.5390C>A p.A1797D | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MYO1A | c.2946A>C p.K982N | Missense Mutation (SNP) | VAF 189/626 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- NBPF15 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 81/604 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAPD3 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NEFM | c.2200G>C p.A734P | Missense Mutation (SNP) | VAF 97/490 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFKB1 | c.2027_2045del p.D676Gfs*44 (on ENST00000394820 / NM_001382627.1; = p.D677Gfs*44 on NM_003998.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 94/406 reads (23%) | called by mutect2, pindel, varscan2
- NSUN2 | c.1258G>T p.G420* | Nonsense Mutation (SNP) | VAF 40/224 reads (18%) | called by muse, mutect2, varscan2
- NTM | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- NUP98 | c.2513A>G p.K838R | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OCA2 | c.2285G>A p.G762D | Missense Mutation (SNP) | VAF 116/562 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2L5 | c.920T>A p.I307N | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.279); called by muse, varscan2
- OR4C46 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 28/541 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.04); called by muse, mutect2
- OR4C4P | n.333G>C | Splice Region (SNP) | VAF 46/168 reads (27%) | called by muse, mutect2, varscan2
- OR52N1 | c.629del p.G210Afs*13 | Frame Shift Del (DEL) | VAF 109/416 reads (26%) | called by mutect2, pindel, varscan2
- OR5A1 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8G1 | c.465T>G p.C155W | Missense Mutation (SNP) | VAF 40/334 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- P4HA1 | c.1264G>T p.V422F | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- PANX3 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PAPPA2 | c.5291C>A p.S1764Y | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PCNX2 | c.5714A>G p.Q1905R | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE1C | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- PLCXD3 | c.554G>T p.W185L | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PLPPR4 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- PMVK | c.69C>G p.D23E | Missense Mutation (SNP) | VAF 20/345 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- POC1B | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROKR1 | c.999C>G p.S333R | Missense Mutation (SNP) | VAF 27/456 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRORP | c.1579G>C p.A527P | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.755); called by muse, mutect2
- PTPN14 | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- PTPRO | c.2061G>T p.M687I | Missense Mutation (SNP) | VAF 239/457 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- RAD9A | c.35-4G>T | Splice Region (SNP) | VAF 77/448 reads (17%) | called by muse, mutect2, varscan2
- RBM3 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- RBM3 | c.209A>T p.E70V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RESF1 | c.2994G>T p.L998F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by mutect2, varscan2
- RGS7 | c.794G>T p.W265L | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RIMS1 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 225/606 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- RNF157 | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- RPL11 | c.382G>C p.D128H (on ENST00000374550 / NM_001199802.1; = p.D129H on NM_000975.5) | Missense Mutation (SNP) | VAF 117/385 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RPTOR | c.1212G>T p.R404= | Splice Region (SNP) | VAF 177/413 reads (43%) | called by muse, mutect2, varscan2
- RRP12 | c.1923A>T p.K641N | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- SATB2 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SGCE | c.1360C>T p.Q454* (on ENST00000647096; = p.Q418* on NM_003919.3) | Nonsense Mutation (SNP) | VAF 86/416 reads (21%) | called by muse, mutect2, varscan2
- SLC45A2 | c.1219C>G p.L407V | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.058); called by muse, mutect2
- SLC5A12 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SMARCA2 | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SOGA3 | c.2392T>C p.F798L | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS3 | c.3400G>A p.V1134I | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SPEG | c.9479C>T p.P3160L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRRM3 | c.1517C>A p.S506Y | Missense Mutation (SNP) | VAF 25/361 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SSC4D | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 78/528 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- TECPR1 | c.3236G>T p.C1079F | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2
- TG | c.3800A>C p.E1267A | Missense Mutation (SNP) | VAF 102/512 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TMEM132C | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- TMEM200A | c.690A>C p.E230D | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TOMM5 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TP73 | c.1906C>G p.H636D | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TRIM51 | c.922A>T p.S308C | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TRPC7 | c.1290A>T p.R430S | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TSGA10IP | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSPAN14 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TSSK3 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 92/315 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- TYK2 | c.364G>C p.V122L | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- U2SURP | c.2936G>C p.S979T | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBA52 | c.192G>A p.E64= | Splice Region (SNP) | VAF 33/240 reads (14%) | called by muse, mutect2, varscan2
- UBAC1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, varscan2
- USH2A | c.14179T>G p.W4727G | Missense Mutation (SNP) | VAF 158/385 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- USH2A | c.8606C>T p.P2869L | Missense Mutation (SNP) | VAF 113/337 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP7 | c.1622_1624del p.V541del | In Frame Del (DEL) | VAF 24/139 reads (17%) | called by pindel, varscan2
- XK | c.502G>T p.G168* | Nonsense Mutation (SNP) | VAF 101/186 reads (54%) | called by muse, mutect2, varscan2
- ZNF280B | c.1266T>G p.F422L | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ZNF442 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2
- ZNF479 | c.1491A>T p.E497D | Missense Mutation (SNP) | VAF 70/477 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ZNF766 | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 179/416 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCG4 | c.1671C>G p.T557= | Silent (SNP) | VAF 67/309 reads (22%) | called by muse, mutect2, varscan2
- ADGB | c.3288A>G p.R1096= | Silent (SNP) | VAF 71/218 reads (33%) | called by muse, mutect2, varscan2
- ANKRD11 | c.5205C>T p.L1735= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV56357326; called by muse, mutect2, varscan2
- ARPP21 | c.429T>C p.D143= | Silent (SNP) | VAF 36/192 reads (19%) | called by muse, mutect2, varscan2
- BET1L | c.255G>A p.R85= | Silent (SNP) | VAF 48/369 reads (13%) | called by muse, mutect2, varscan2
- BRD2 | c.1506G>A p.E502= | Silent (SNP) | VAF 67/497 reads (13%) | called by muse, mutect2, varscan2
- CCDC96 | c.1233G>T p.L411= | Silent (SNP) | VAF 9/273 reads (3%) | catalogued as COSV59509249; called by muse, mutect2
- CENPJ | c.993T>C p.I331= | Silent (SNP) | VAF 39/239 reads (16%) | catalogued as rs569778066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP170 | c.3006A>G p.R1002= | Silent (SNP) | VAF 98/506 reads (19%) | called by muse, mutect2, varscan2
- COL11A2 | c.2061C>T p.D687= (on ENST00000341947 / NM_080680.3; = p.D580= on NM_080679.2) | Silent (SNP) | VAF 67/374 reads (18%) | catalogued as rs764335860, COSV59497360; called by muse, mutect2, varscan2
- CPEB3 | c.1074G>A p.R358= | Silent (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- CRLF2 | c.447G>A p.E149= | Silent (SNP) | VAF 26/482 reads (5%) | called by muse, mutect2
- CROCC | c.2802G>C p.G934= | Silent (SNP) | VAF 111/674 reads (16%) | catalogued as rs1409830797; called by muse, varscan2
- CYP2D6 | c.1125C>A p.T375= | Silent (SNP) | VAF 232/755 reads (31%) | called by muse, mutect2, varscan2
- CYP7A1 | c.99T>C p.P33= | Silent (SNP) | VAF 62/233 reads (27%) | called by muse, mutect2, varscan2
- DENND6B | c.588G>T p.A196= | Silent (SNP) | VAF 77/445 reads (17%) | called by muse, mutect2, varscan2
- DST | c.2160G>A p.E720= (on ENST00000361203 / NM_001374722.1; = p.E394= on NM_001723.6) | Silent (SNP) | VAF 62/446 reads (14%) | called by muse, mutect2, varscan2
- DYRK2 | c.456C>A p.T152= (on ENST00000344096 / NM_006482.3; = p.T79= on NM_003583.4) | Silent (SNP) | VAF 42/136 reads (31%) | called by muse, mutect2, varscan2
- EIF4EBP1 | c.204C>A p.T68= | Silent (SNP) | VAF 60/288 reads (21%) | called by muse, mutect2, varscan2
- FAT3 | c.4311T>C p.D1437= | Silent (SNP) | VAF 48/191 reads (25%) | called by muse, mutect2, varscan2
- FOSL1 | c.63C>T p.P21= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs981029020; called by muse, mutect2, varscan2
- GAS7 | c.156C>T p.F52= | Silent (SNP) | VAF 392/748 reads (52%) | catalogued as rs1567629570; called by muse, mutect2, varscan2
- GCN1 | c.7392C>T p.A2464= | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as rs757222671; called by muse, mutect2, varscan2
- GPR15 | c.765G>T p.L255= | Silent (SNP) | VAF 76/159 reads (48%) | called by muse, mutect2, varscan2
- GRAMD1B | c.75G>A p.E25= | Silent (SNP) | VAF 54/352 reads (15%) | called by muse, mutect2, varscan2
- GRIP2 | c.1287C>A p.P429= (on ENST00000619221; = p.P332= on NM_001080423.4) | Silent (SNP) | VAF 75/201 reads (37%) | called by muse, mutect2, varscan2
- HAS1 | c.378G>A p.A126= | Silent (SNP) | VAF 26/377 reads (7%) | catalogued as rs1186469527; called by muse, mutect2
- HCN1 | c.2394C>G p.S798= | Silent (SNP) | VAF 98/292 reads (34%) | called by muse, mutect2, varscan2
- IGFN1 | c.2247G>T p.A749= (on ENST00000295591 / NM_001367841.1; = p.A3206= on NM_001164586.2) | Silent (SNP) | VAF 29/180 reads (16%) | called by muse, mutect2, varscan2
- KCNG1 | c.42C>T p.S14= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs766155892, COSV65370490; called by muse, mutect2, varscan2
- LDHAL6B | c.960T>C p.H320= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as rs757467972; called by muse, mutect2, varscan2
- LRRIQ1 | c.4368C>G p.T1456= | Silent (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- MMP25 | c.297G>A p.A99= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as rs373405202; called by muse, mutect2, varscan2
- MROH2A | c.3774A>T p.G1258= | Silent (SNP) | VAF 69/384 reads (18%) | catalogued as rs760164391; called by muse, mutect2, varscan2
- NAA50 | c.168A>G p.V56= | Silent (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2, varscan2
- NLRX1 | c.627A>T p.P209= | Silent (SNP) | VAF 127/450 reads (28%) | called by muse, mutect2, varscan2
- NSUN2 | c.1257T>C p.T419= | Silent (SNP) | VAF 40/221 reads (18%) | called by muse, mutect2, varscan2
- OR2M7 | c.438C>A p.A146= | Silent (SNP) | VAF 58/521 reads (11%) | catalogued as rs960556956, COSV100522704; called by muse, mutect2, varscan2
- OR2T33 | c.57C>G p.T19= | Silent (SNP) | VAF 56/210 reads (27%) | called by muse, varscan2
- OR51V1 | c.375G>C p.R125= | Silent (SNP) | VAF 37/124 reads (30%) | called by muse, mutect2, varscan2
- PCDH15 | c.2563C>A p.R855= | Silent (SNP) | VAF 90/266 reads (34%) | catalogued as rs138010738; called by muse, mutect2, varscan2
- PFKFB1 | c.213A>G p.T71= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as rs779699593; called by muse, mutect2, varscan2
- PIGW | c.634C>T p.L212= | Silent (SNP) | VAF 44/270 reads (16%) | catalogued as rs1177424625; called by muse, mutect2, varscan2
- PLCH2 | c.3546C>G p.P1182= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as rs558901596, COSV53945029; called by muse, mutect2
- PLXND1 | c.5673G>T p.A1891= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as COSV60717072, COSV60720050; called by muse, mutect2, varscan2
- PLXND1 | c.1224C>T p.F408= | Silent (SNP) | VAF 62/555 reads (11%) | called by muse, varscan2
- POM121L2 | c.1737T>A p.P579= | Silent (SNP) | VAF 87/356 reads (24%) | called by muse, mutect2, varscan2
- POTEG | c.411A>G p.R137= | Silent (SNP) | VAF 103/2351 reads (4%) | called by muse, mutect2
- PRPF31 | c.984C>T p.F328= | Silent (SNP) | VAF 250/558 reads (45%) | catalogued as rs202206056; called by muse, mutect2, varscan2
- PTPRQ | c.6339A>T p.P2113= (on ENST00000616559; = p.P2080= on NM_001145026.2) | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- RBMXL2 | c.78C>T p.A26= | Silent (SNP) | VAF 44/468 reads (9%) | catalogued as COSV100182612, COSV100182617; called by muse, mutect2
- RETNLB | c.174C>A p.V58= | Silent (SNP) | VAF 59/440 reads (13%) | called by muse, mutect2, varscan2
- RND2 | c.57C>T p.G19= | Silent (SNP) | VAF 34/366 reads (9%) | called by muse, mutect2
- SEC23B | c.312G>A p.V104= | Silent (SNP) | VAF 83/838 reads (10%) | called by muse, mutect2, varscan2
- SERPINA9 | c.1140T>C p.D380= | Silent (SNP) | VAF 63/352 reads (18%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.1305C>T p.H435= | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as rs766030250; called by muse, mutect2, varscan2
- SLC37A1 | c.690G>C p.V230= | Silent (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- SPATS1 | c.330T>C p.S110= | Silent (SNP) | VAF 61/250 reads (24%) | called by muse, mutect2, varscan2
- SPTLC3 | c.1299A>G p.Q433= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- STRC | c.3258G>T p.L1086= | Silent (SNP) | VAF 51/462 reads (11%) | called by muse, varscan2
- TBX21 | c.849C>T p.A283= | Silent (SNP) | VAF 112/275 reads (41%) | catalogued as COSV51597919; called by muse, mutect2, varscan2
- TCF20 | c.5043G>A p.A1681= | Silent (SNP) | VAF 143/386 reads (37%) | catalogued as rs763678858, COSV100166955; called by muse, mutect2, varscan2
- TEP1 | c.1110C>T p.A370= | Silent (SNP) | VAF 55/511 reads (11%) | catalogued as COSV53001306; called by muse, mutect2, varscan2
- TLR4 | c.486C>A p.I162= (on ENST00000355622 / NM_138554.5; = p.I122= on NM_003266.4) | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV62924013; called by muse, mutect2, varscan2
- TRIM51GP | c.126C>T p.N42= | Silent (SNP) | VAF 120/643 reads (19%) | called by muse, mutect2, varscan2
- TRPM6 | c.3663C>A p.T1221= | Silent (SNP) | VAF 14/105 reads (13%) | called by muse, mutect2, varscan2
- UGGT2 | c.3381A>C p.A1127= | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2
- UNC13A | c.805C>T p.L269= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs1224454361; called by muse, varscan2
- USP20 | c.1935C>T p.I645= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as rs775238985; called by muse, mutect2, varscan2
- ZEB1 | c.1200T>C p.G400= | Silent (SNP) | VAF 51/104 reads (49%) | called by muse, mutect2, varscan2
- ZNF28 | c.54T>C p.S18= | Silent (SNP) | VAF 76/595 reads (13%) | catalogued as COSV60423552; called by muse, mutect2, varscan2
- ZNF536 | c.2751C>A p.S917= | Silent (SNP) | VAF 80/329 reads (24%) | catalogued as COSV62833896; called by muse, mutect2, varscan2
- ZNF552 | c.27C>G p.P9= | Silent (SNP) | VAF 27/318 reads (8%) | catalogued as rs927958474; called by muse, mutect2
- ZNHIT6 | c.942G>C p.R314= | Silent (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- ACADL | c.371+51C>T | Intron (SNP) | VAF 13/158 reads (8%) | catalogued as rs764143112; called by muse, mutect2
- ADGRA1 | c.4-1301C>T | Intron (SNP) | VAF 74/200 reads (37%) | catalogued as rs1272972187; called by muse, mutect2, varscan2
- AL356414.1 | n.538G>C | RNA (SNP) | VAF 71/238 reads (30%) | called by muse, mutect2, varscan2
- ALAD | c.*40G>T | 3'UTR (SNP) | VAF 69/311 reads (22%) | called by muse, mutect2, varscan2
- BAAT | c.*42T>C | 3'UTR (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2
- BTBD7 | c.-147C>G | 5'UTR (SNP) | VAF 21/379 reads (6%) | called by muse, mutect2
- CANX | c.-130C>G | 5'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- CIDEC | c.-26+182G>A | Intron (SNP) | VAF 19/79 reads (24%) | catalogued as rs765152542; called by muse, mutect2, varscan2
- CROCC2 | c.4557+480G>C | Intron (SNP) | VAF 27/217 reads (12%) | catalogued as rs1477538629; called by muse, mutect2, varscan2
- CYP24A1 | c.449+13C>G | Intron (SNP) | VAF 82/506 reads (16%) | called by muse, mutect2, varscan2
- DNAH14 | c.2939-21C>T | Intron (SNP) | VAF 71/244 reads (29%) | called by muse, mutect2, varscan2
- ETV2 | c.70+10C>T | Intron (SNP) | VAF 31/206 reads (15%) | catalogued as rs532601843; called by muse, mutect2, varscan2
- FAM161A | c.*27T>G | 3'UTR (SNP) | VAF 95/445 reads (21%) | called by muse, mutect2, varscan2
- FAM183BP | n.876C>T | RNA (SNP) | VAF 41/252 reads (16%) | called by muse, mutect2, varscan2
- FAM215A | n.330C>T | RNA (SNP) | VAF 87/370 reads (24%) | called by muse, mutect2, varscan2
- FAM229A | c.134+28G>C | Intron (SNP) | VAF 46/226 reads (20%) | called by muse, mutect2, varscan2
- FRMPD2B | n.611G>C | RNA (SNP) | VAF 95/302 reads (31%) | called by muse, mutect2, varscan2
- FRMPD2B | n.612G>T | RNA (SNP) | VAF 96/302 reads (32%) | called by muse, mutect2, varscan2
- FSHR | c.374+2545C>T | Intron (SNP) | VAF 33/175 reads (19%) | called by muse, mutect2, varscan2
- FUZ | c.492+23T>G | Intron (SNP) | VAF 56/518 reads (11%) | called by muse, mutect2
- GPT | c.819+27C>T | Intron (SNP) | VAF 135/511 reads (26%) | catalogued as COSV52952454; called by muse, mutect2, varscan2
- GUCY2EP | n.1052G>T | RNA (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- HEXD | c.1061+35C>T | Intron (SNP) | VAF 32/415 reads (8%) | catalogued as rs1261199770; called by muse, mutect2
- HSP90AA4P | n.373G>A | RNA (SNP) | VAF 63/251 reads (25%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.297G>T | RNA (SNP) | VAF 102/965 reads (11%) | called by muse, mutect2, varscan2
- IL2RG | c.116-80C>A | Intron (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- KIFC3 | c.315+6291C>T | Intron (SNP) | VAF 81/183 reads (44%) | catalogued as rs782705609; called by muse, mutect2, varscan2
- LGALS8 | c.549+166C>G | Intron (SNP) | VAF 75/285 reads (26%) | called by muse, mutect2, varscan2
- LRRC27 | chr10:132331675 G>C | 5'Flank (SNP) | VAF 32/127 reads (25%) | catalogued as rs763570586; called by muse, mutect2
- MIR3680-2 | chr16:29594888 T>A | 3'Flank (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2, varscan2
- OR51A4 | chr11:4944154 A>T | 3'Flank (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- OR51F5P | n.669C>G | RNA (SNP) | VAF 42/175 reads (24%) | called by muse, mutect2, varscan2
- OTOR | c.*21A>G | 3'UTR (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- PADI3 | c.-1C>A | 5'UTR (SNP) | VAF 145/317 reads (46%) | called by muse, mutect2, varscan2
- PDZRN4 | c.844-46480C>G | Intron (SNP) | VAF 118/236 reads (50%) | called by muse, mutect2, varscan2
- PPP2R5C | c.630-17A>G | Intron (SNP) | VAF 10/51 reads (20%) | catalogued as rs1283052256; called by muse, mutect2, varscan2
- SLC25A39 | c.517+23G>C | Intron (SNP) | VAF 91/191 reads (48%) | called by muse, mutect2, varscan2
- SNORD116-12 | n.12G>A | RNA (SNP) | VAF 19/236 reads (8%) | catalogued as rs772723675; called by muse, mutect2
- TSSC2 | n.288-5492A>T | Intron (SNP) | VAF 128/421 reads (30%) | called by muse, mutect2, varscan2
- Unknown | chr17:43379203 A>G | IGR (SNP) | VAF 38/254 reads (15%) | catalogued as rs1449409466; called by muse, mutect2, varscan2
- VSTM2B | c.-17C>A | 5'UTR (SNP) | VAF 104/361 reads (29%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071738 del G | 3'Flank (DEL) | VAF 106/577 reads (18%) | called by mutect2, pindel, varscan2
- ZNF781 | c.*56G>T | 3'UTR (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- ZNF99 | c.*3168G>C | 3'UTR (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
